Somatic mutation profile of tumor specimen TCGA-2A-AAYO-01A (aliquot TCGA-2A-AAYO-01A-11D-A41K-08) from TCGA case TCGA-2A-AAYO, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 58.0 years (21,183 days).
Specimen TCGA-2A-AAYO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1fdd1463-68f0-4dcd-ac9a-e15cfdccdc55.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2A-AAYO-10A (Blood Derived Normal), aliquot TCGA-2A-AAYO-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c1ec7c9-fe7f-4e1c-8940-16e152aad534

The open-access MAF lists 22 somatic variants for this specimen: 20 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 17, Silent 2, Frame Shift Del 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTR3B | c.986G>A p.R329K | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99754384; called by muse, mutect2, varscan2
- ITGAD | c.2858G>A p.R953H | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as rs761068465, COSV99791457; called by muse, mutect2, varscan2
- JAG1 | c.3377T>C p.I1126T | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99653333; called by muse, mutect2, varscan2
- MGLL | c.217T>C p.F73L (on ENST00000398104 / NM_001003794.2; = p.F83L on NM_007283.6) | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs371613630; called by muse, mutect2, varscan2
- NES | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs886501238, COSV100957953; called by mutect2, varscan2
- OR6X1 | c.907A>G p.M303V | Missense Mutation (SNP) | VAF 64/202 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100020632; called by muse, mutect2, varscan2
- PRAMEF20 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 137/331 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1054713600; called by muse, mutect2, varscan2
- REM2 | c.467T>C p.I156T | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV99944736; called by muse, mutect2, varscan2
- RP1 | c.5512C>T p.R1838C | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as rs1240493980, COSV55123358; called by muse, mutect2, varscan2
- SEMA6A | c.1286C>T p.A429V | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99145898; called by muse, mutect2
- SLC45A1 | c.2203G>C p.D735H | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV99239430; called by muse, mutect2, varscan2
- SPTB | c.5210G>A p.R1737Q | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.476); catalogued as rs561976171; called by muse, mutect2, varscan2
- SYNE1 | c.1294C>G p.Q432E (on ENST00000367255 / NM_182961.4; = p.Q439E on NM_033071.3) | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as COSV99574535; called by muse, mutect2, varscan2
- TNRC6C | c.4369C>G p.L1457V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100050493; called by muse, mutect2
- TTN | c.80134G>A p.E26712K (on ENST00000591111; = p.E19288K on NM_003319.4) | Missense Mutation (SNP) | VAF 49/142 reads (35%) | PolyPhen benign (0.385); catalogued as COSV100624054; called by muse, mutect2, varscan2
- ZC3H18 | c.2040G>T p.R680S | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99964337; called by muse, mutect2, varscan2
- ZMYND15 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.014); catalogued as rs1303020954, COSV52643306; called by muse, mutect2, varscan2
- OMP | c.447_466del p.E150Lfs*5 | Frame Shift Del (DEL) | VAF 19/84 reads (23%) | called by mutect2, pindel, varscan2
- RGP1 | c.814_815del p.R272Tfs*26 | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | called by mutect2, pindel, varscan2
- SMARCA1 | c.1921dup p.R641Kfs*14 | Frame Shift Ins (INS) | VAF 23/41 reads (56%) | called by mutect2, pindel, varscan2
- NPR1 | c.2469C>T p.Y823= | Silent (SNP) | VAF 38/120 reads (32%) | catalogued as rs145546823; called by muse, mutect2, varscan2
- WDPCP | c.759C>A p.A253= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as rs1237491859, COSV99706362; called by muse, mutect2, varscan2
